Somatic mutation profile of tumor specimen HCM-CSHL-0242-C18-01B (aliquot HCM-CSHL-0242-C18-01B-01D-A78L-36) from HCMI case HCM-CSHL-0242-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.1 years (26,343 days).
Specimen HCM-CSHL-0242-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d3cc02-3c16-48f0-b85a-160707eee7f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0242-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0242-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/445aa596-4a12-4266-9507-3a7b4cea8c5c

The open-access MAF lists 2,570 somatic variants for this specimen: 1,757 protein-altering or splice-affecting, 486 silent, 327 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,253, Silent 486, Frame Shift Del 324, Intron 167, Frame Shift Ins 70, 3'UTR 43, 5'UTR 42, Nonsense Mutation 34, RNA 33, Splice Region 30, Splice Site 25, 5'Flank 25.

Variants (750 of 2,570; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.352); catalogued as rs746800707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 109/514 reads (21%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AIRE | c.1103dup p.L370Afs*2 | Frame Shift Ins (INS) | VAF 40/125 reads (32%) | catalogued as rs387906293; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 125/441 reads (28%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/834 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A5 | c.1376del p.P459Qfs*15 | Frame Shift Del (DEL) | VAF 42/86 reads (49%) | catalogued as rs104886113, CD961911; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EYA4 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 68/914 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2
- MMP2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs121912953, CM012155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs397516135, HM0650, COSV62519421; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NAGLU | c.648del p.S217Pfs*22 | Frame Shift Del (DEL) | VAF 83/243 reads (34%) | catalogued as rs760370189; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 74/263 reads (28%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 51/118 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RSPH1 | c.680dup p.P228Afs*15 | Frame Shift Ins (INS) | VAF 98/350 reads (28%) | catalogued as rs556286752; ClinVar: pathogenic; called by pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 65/118 reads (55%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 124/426 reads (29%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 149/346 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 77/249 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326753, COSV59327496; called by muse, mutect2, varscan2
- A2ML1 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755702632, COSV55289544; called by muse, mutect2, varscan2
- AACS | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780717330; called by muse, mutect2, varscan2
- AADAC | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as rs146809751; called by muse, mutect2, varscan2
- ABCA12 | c.6739G>A p.G2247S (on ENST00000272895 / NM_173076.3; = p.G1929S on NM_015657.3) | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55972901; called by muse, mutect2, varscan2
- ABCA13 | c.6205C>A p.L2069I | Missense Mutation (SNP) | VAF 194/406 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV70033729; called by muse, mutect2, varscan2
- ABCA3 | c.4834C>T p.R1612W | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs748547109; called by muse, mutect2, varscan2
- ABCC4 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759564295, COSV65313323; called by muse, mutect2, varscan2
- ABHD2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61776627; called by muse, varscan2
- ABHD2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs374166259; called by muse, varscan2
- ABLIM1 | c.1934-1G>T p.X645_splice | Splice Site (SNP) | VAF 99/302 reads (33%) | catalogued as COSV53302209; called by muse, mutect2, varscan2
- AC013477.1 | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 159/421 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53653975; called by muse, mutect2, varscan2
- AC244197.3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs369603623, COSV61712782; called by muse, mutect2, varscan2
- AC244197.3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 127/159 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs782445506; ClinVar: benign; called by muse, mutect2, varscan2
- ACAN | c.4594G>A p.E1532K | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.914); catalogued as rs755141817; called by muse, mutect2, varscan2
- ACSF3 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58076568; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 238/336 reads (71%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS19 | c.1782C>A p.C594* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV99178851; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140237789; called by muse, mutect2, varscan2
- ADAR | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 108/315 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as rs747462052, COSV99425769; called by muse, mutect2, varscan2
- ADCY10 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183008856; called by muse, mutect2, varscan2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- ADGRB2 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748743741; called by muse, mutect2, varscan2
- ADGRB3 | c.2498C>T p.T833M | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV53257399, COSV53258820; called by muse, mutect2, varscan2
- ADGRE2 | c.2218A>G p.I740V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.921); catalogued as rs758592313; called by muse, mutect2, varscan2
- ADGRL1 | c.754G>A p.A252T (on ENST00000340736 / NM_001008701.3; = p.A247T on NM_014921.5) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226166895; called by muse, mutect2
- ADORA2A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs201181215; called by muse, mutect2, varscan2
- AFF2 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 129/182 reads (71%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99667068; called by muse, mutect2, varscan2
- AGMAT | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.563); catalogued as rs377410185; called by mutect2, varscan2
- AGTR2 | c.419T>G p.V140G | Missense Mutation (SNP) | VAF 182/247 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV64157021; called by muse, mutect2, varscan2
- AHDC1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs766550931; called by muse, mutect2, varscan2
- AKAP13 | c.7608+4C>T | Splice Region (SNP) | VAF 59/199 reads (30%) | catalogued as rs765320866; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 441/583 reads (76%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKR1C8P | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs782390528; called by muse, mutect2
- AL136295.1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1037307556; called by muse, mutect2, varscan2
- ALDH18A1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 206/530 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1183327194; called by muse, mutect2, varscan2
- AMBRA1 | c.1067C>T p.S356L (on ENST00000458649 / NM_001367468.1; = p.S266L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/143 reads (80%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.143); catalogued as rs144750570; called by muse, mutect2, varscan2
- AMPD2 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs141742198; called by muse, mutect2, varscan2
- ANGEL1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs775354721, COSV51873019; called by muse, mutect2, varscan2
- ANKH | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 134/358 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.542); catalogued as rs1190164920, COSV52479201; called by muse, mutect2, varscan2
- ANKLE1 | c.69del p.E24Sfs*54 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs139615873; called by mutect2, pindel, varscan2
- ANKRD13B | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs769516438; called by muse, mutect2, varscan2
- ANKRD13C | c.211A>G p.N71D | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as rs1291258023; called by muse, mutect2, varscan2
- ANKRD65 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1410096668; called by muse, mutect2, varscan2
- ANO2 | c.464G>A p.R155Q (on ENST00000356134 / NM_001278597.3; = p.R159Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs746661048; called by muse, mutect2, varscan2
- ANXA13 | c.451dup p.I151Nfs*9 | Frame Shift Ins (INS) | VAF 111/342 reads (32%) | catalogued as rs759218332; called by mutect2, varscan2
- AP3D1 | c.2581_2586del p.K861_K862del | In Frame Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs1325272641; called by mutect2, pindel, varscan2
- AP3M1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs541963645; called by muse, mutect2, varscan2
- APBA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762371853, COSV55227236; called by muse, mutect2, varscan2
- APBA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs564159274, COSV55232051; called by muse, mutect2, varscan2
- APC | c.1264del p.E422Sfs*32 | Frame Shift Del (DEL) | VAF 81/220 reads (37%) | catalogued as CM106640, CX056897, COSV104378826; called by mutect2, pindel, varscan2
- APC2 | c.6205G>A p.G2069S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1391507735; called by muse, mutect2, varscan2
- APOBEC3F | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1408166368; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- AQP7 | c.189del p.K63Nfs*31 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | catalogued as COSV53008175; called by mutect2, pindel, varscan2
- ARFGAP2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1342213501; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 72/214 reads (34%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF3 | c.4966G>A p.A1656T | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as COSV99294786; called by muse, mutect2
- ARHGAP35 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68336836; called by muse, mutect2, varscan2
- ARHGEF12 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34726241; called by muse, mutect2, varscan2
- ARHGEF40 | c.3820C>T p.H1274Y | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as COSV53879668; called by muse, mutect2, varscan2
- ARL10 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV53798213; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 127/345 reads (37%) | catalogued as rs753865255; called by mutect2, varscan2
- ASAP2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55631989; called by muse, mutect2, varscan2
- ASNS | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 116/230 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51555665; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ASPRV1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as rs749880547, COSV100208468; called by muse, varscan2
- ATAD3C | c.512G>T p.R171M | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66483228, COSV66483318; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.354); catalogued as rs746559979; called by muse, mutect2, varscan2
- ATF7IP2 | c.1312del p.I438Lfs*21 | Frame Shift Del (DEL) | VAF 22/236 reads (9%) | catalogued as rs763946306; called by mutect2, pindel
- ATG16L2 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770072481; called by muse, mutect2, varscan2
- ATG2A | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773884095; called by muse, mutect2, varscan2
- ATP13A2 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as rs764988645, COSV58700082; called by muse, mutect2, varscan2
- ATP2A2 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1352765498; called by muse, mutect2, varscan2
- ATP2B4 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779972851, COSV58174463; called by muse, mutect2, varscan2
- ATP2C1 | c.75del p.A26Qfs*21 | Frame Shift Del (DEL) | VAF 170/573 reads (30%) | catalogued as rs1559936852, COSV60757077; called by pindel, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 52/122 reads (43%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- AXIN2 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747647668, COSV61059552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT6 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55420101; called by mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 56/156 reads (36%) | catalogued as rs35951843; called by mutect2, varscan2
- BAIAP3 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1056198053; called by muse, varscan2
- BCL2 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV61386068; called by mutect2, varscan2
- BEND4 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV72469451; called by muse, mutect2
- BICD2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs778940849; called by muse, mutect2, varscan2
- BICRA | c.1320del p.A442Pfs*2 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1361394574; called by mutect2, pindel, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 48/168 reads (29%) | catalogued as rs758822270; called by mutect2, varscan2
- BMP15 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as rs781848548, COSV53140331; called by muse, mutect2, varscan2
- BOP1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1435772457; called by muse, mutect2, varscan2
- BPIFB3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs777030919; called by muse, mutect2, varscan2
- BPNT1 | c.911del p.N304Mfs*20 | Frame Shift Del (DEL) | VAF 62/181 reads (34%) | catalogued as rs1210209988; called by mutect2, pindel, varscan2
- BRD4 | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1456519129; called by muse, mutect2, varscan2
- BRMS1L | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1023777427, COSV53762371; called by muse, mutect2, varscan2
- C10orf71 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV60507301; called by muse, mutect2, varscan2
- C19orf12 | c.310G>A p.A104T (on ENST00000392278 / NM_001031726.3; = p.A93T on NM_031448.6) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs964208776; ClinVar: uncertain significance; called by muse, mutect2
- C1QTNF4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100209256; called by muse, mutect2, varscan2
- C1orf174 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as rs751234275, COSV100851824; called by muse, mutect2, varscan2
- C1orf210 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV70682505; called by muse, mutect2, varscan2
- C2CD4D | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100787613; called by muse, mutect2
- C2orf81 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99292499; called by muse, mutect2, varscan2
- C3 | c.304del p.R102Afs*5 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as CM940211, COSV99836473; called by mutect2, pindel, varscan2
- C3 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV55571750; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 61/182 reads (34%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C6orf118 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs140022567, COSV57817681; called by muse, mutect2, varscan2
- C6orf132 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1321277113, COSV59375727; called by muse, mutect2, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 155/393 reads (39%) | catalogued as rs750735753; called by mutect2, pindel, varscan2
- CACNA1B | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs890458453; called by muse, mutect2, varscan2
- CACNA1H | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs574809183; called by muse, mutect2, varscan2
- CAD | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779056625, COSV53024811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 67/199 reads (34%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMTA1 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs765363667; called by muse, mutect2
- CAND1 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.757); catalogued as rs1218716660; called by muse, mutect2
- CAPN15 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1458886277; called by muse, mutect2, varscan2
- CARD10 | c.1578dup p.S527Qfs*11 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs35832225; called by mutect2, varscan2
- CARD14 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.62); catalogued as rs965855312; called by muse, mutect2, varscan2
- CARM1 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.587); catalogued as COSV59002097; called by muse, mutect2, varscan2
- CASP10 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53780656; called by muse, mutect2, varscan2
- CASP4 | c.128del p.K43Rfs*37 | Frame Shift Del (DEL) | VAF 148/536 reads (28%) | catalogued as rs772291949; called by mutect2, pindel, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 132/370 reads (36%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP8 | c.1063T>G p.F355V (on ENST00000432109 / NM_033355.3; = p.F372V on NM_001228.4) | Missense Mutation (SNP) | VAF 116/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51847031; called by muse, mutect2, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 125/412 reads (30%) | catalogued as rs751612825; called by pindel, varscan2
- CCDC185 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as rs1173730581, COSV64822056; called by muse, mutect2, varscan2
- CCDC40 | c.2519T>C p.L840P | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66473010; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 39/106 reads (37%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC66 | c.254del p.N85Mfs*3 (on ENST00000394672 / NM_001353147.1; = p.N51Mfs*3 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 128/388 reads (33%) | catalogued as rs751844604; called by mutect2, varscan2
- CCDC70 | c.151dup p.I51Nfs*72 | Frame Shift Ins (INS) | VAF 66/162 reads (41%) | catalogued as rs752919705; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 100/273 reads (37%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC96 | c.973_975del p.K325del | In Frame Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1463309934; called by mutect2, pindel, varscan2
- CCDC9B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.855); catalogued as rs1345259734, COSV66876545; called by muse, mutect2, varscan2
- CCER1 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1484068156; called by muse, mutect2, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCL5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1482072962; called by muse, mutect2, varscan2
- CCNG2 | c.890del p.G297Vfs*15 | Frame Shift Del (DEL) | VAF 67/232 reads (29%) | catalogued as rs745928364; called by mutect2, pindel, varscan2
- CCP110 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 160/535 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs370713605; called by muse, mutect2, varscan2
- CCT3 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs1455894708; called by muse, mutect2, varscan2
- CCT4 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 118/358 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs768770405; called by muse, mutect2, varscan2
- CD276 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs755716069, COSV59202970; called by muse, mutect2, varscan2
- CDCA4 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1431299150; called by muse, mutect2, varscan2
- CDH7 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs780536938, COSV59885635; called by muse, mutect2, varscan2
- CDKN2AIP | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs747819772, COSV56626841; called by muse, mutect2, varscan2
- CDSN | c.1530del p.Q512Sfs*2 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs756296748; called by mutect2, pindel
- CELA3B | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61402951; called by muse, mutect2
- CELF5 | c.102del p.Q35Sfs*5 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV53011441; called by pindel, varscan2
- CELSR1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs752239073, COSV53088286; called by muse, mutect2, varscan2
- CELSR2 | c.5282G>A p.C1761Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs927238797; called by muse, mutect2, varscan2
- CEP104 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs763300107, COSV58214912; called by muse, mutect2, varscan2
- CEP41 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 147/612 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200709703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP63 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1235488221; called by muse, mutect2, varscan2
- CEP85 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs779280111, COSV53330615; called by muse, mutect2, varscan2
- CES5A | c.1624A>G p.T542A (on ENST00000290567 / NM_001143685.2; = p.T492A on NM_145024.3) | Missense Mutation (SNP) | VAF 218/588 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as rs1262275161, COSV51871382; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 55/173 reads (32%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP74 | c.4352A>G p.Y1451C | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs750094787; called by muse, mutect2, varscan2
- CFHR5 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 142/425 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56823704; called by muse, mutect2, varscan2
- CGN | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006810957, COSV99642139; called by muse, mutect2, varscan2
- CGN | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368607138; called by muse, mutect2, varscan2
- CHD2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 149/358 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101244912; called by muse, mutect2, varscan2
- CHD3 | c.3660G>A p.M1220I | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as COSV57878563; called by muse, mutect2, varscan2
- CHPF2 | c.1941_1942insA p.S648Ifs*6 | Frame Shift Ins (INS) | VAF 15/35 reads (43%) | catalogued as COSV50390137; called by mutect2, pindel, varscan2
- CHTF18 | c.365del p.P122Lfs*47 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1442529917; called by mutect2, varscan2
- CIT | c.5896C>A p.L1966M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV55868698; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751344715; called by muse, mutect2, varscan2
- CLCNKB | c.656-3del | Splice Region (DEL) | VAF 48/136 reads (35%) | catalogued as rs1279574325; called by mutect2, pindel, varscan2
- CLDN10 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 266/549 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs760145374; called by muse, mutect2, varscan2
- CLPTM1 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs762373873; called by muse, mutect2, varscan2
- CLU | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201024088; called by muse, mutect2, varscan2
- CMIP | c.1285A>G p.I429V (on ENST00000537098 / NM_198390.2; = p.I335V on NM_030629.3) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.558); catalogued as COSV67699887; called by muse, mutect2
- CMKLR1 | c.475G>A p.A159T (on ENST00000312143 / NM_001142344.2; = p.A157T on NM_004072.3) | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV56439546; called by muse, mutect2, varscan2
- CMTM2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778788831, COSV51748146; called by muse, mutect2, varscan2
- CNTN6 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610791; called by muse, mutect2, varscan2
- CNTNAP4 | c.2700G>T p.Q900H | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs533617576; called by muse, mutect2, varscan2
- COL18A1 | c.1124del p.G375Afs*164 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs528991245; called by mutect2, varscan2
- COL23A1 | c.732C>T p.G244= | Splice Region (SNP) | VAF 46/154 reads (30%) | catalogued as rs1193637344, COSV66787362; called by muse, mutect2, varscan2
- COL6A2 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56004492; called by muse, mutect2, varscan2
- COL7A1 | c.8018C>A p.P2673H | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56476922; called by muse, mutect2, varscan2
- COL7A1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772888814, COSV60391197; called by muse, mutect2, varscan2
- COLEC12 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs200501360; called by muse, mutect2, varscan2
- COPA | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138441444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs182487045, COSV56694512; called by muse, mutect2, varscan2
- CPAMD8 | c.272G>A p.G91D (on ENST00000651564; = p.G44D on NM_015692.5) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52232320; called by muse, mutect2, varscan2
- CPO | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772125020; called by muse, mutect2, varscan2
- CPQ | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753340797, COSV55140372; called by muse, mutect2, varscan2
- CPSF6 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 64/165 reads (39%) | catalogued as COSV99879541; called by muse, mutect2, varscan2
- CR2 | c.734+2T>C p.X245_splice | Splice Site (SNP) | VAF 159/494 reads (32%) | catalogued as rs771175429; called by muse, mutect2, varscan2
- CRB2 | c.612C>T p.N204= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as rs570941986, COSV63504628; called by muse, mutect2, varscan2
- CROCC | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752953125; called by muse, mutect2, varscan2
- CROCC | c.5519G>A p.R1840Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs996889794, COSV100977599; called by muse, mutect2, varscan2
- CSMD2 | c.10205G>A p.R3402H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs779988397, COSV53891776; called by muse, mutect2, varscan2
- CSMD3 | c.2501G>A p.C834Y (on ENST00000297405 / NM_001363185.1; = p.C730Y on NM_052900.3) | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52345312; called by muse, mutect2, varscan2
- CSNK1G2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs758407129; called by muse, mutect2, varscan2
- CSPG4 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367600030; called by muse, mutect2, varscan2
- CTDSPL2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs779587261, COSV52948373; called by muse, mutect2, varscan2
- CUBN | c.9350G>A p.R3117H | Missense Mutation (SNP) | VAF 33/614 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs184750323, COSV64707712; called by muse, mutect2
- CUL2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66081586; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs772257590; called by mutect2, varscan2
- CYP2E1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs76138620; called by muse, mutect2, varscan2
- CYP3A7 | c.644C>A p.P215Q | Missense Mutation (SNP) | VAF 287/1006 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV60481380; called by muse, mutect2, varscan2
- CYP4F3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs774751788, COSV99657972; called by muse, mutect2, varscan2
- DCST1 | c.174del p.L59Sfs*4 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs746224810; called by mutect2, pindel, varscan2
- DDIT4L | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56767166; called by muse, mutect2, varscan2
- DDX10 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs774783994, COSV59431123; called by muse, mutect2, varscan2
- DDX31 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257083396; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 116/258 reads (45%) | catalogued as rs778036194; called by mutect2, varscan2
- DFFA | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755323383; called by muse, mutect2, varscan2
- DHDDS | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs912516570, COSV52577940; called by muse, mutect2
- DHDH | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs772545415, COSV55481986; called by muse, mutect2
- DHX16 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs749340666; called by muse, mutect2, varscan2
- DHX37 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764894461; called by muse, mutect2, varscan2
- DIP2B | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV56583374, COSV56583491; called by muse, mutect2
- DISC1 | c.1946T>C p.L649P | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1350953507; called by muse, mutect2, varscan2
- DLEU7 | c.94del p.D32Tfs*59 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as rs867917062; called by mutect2, pindel, varscan2
- DLK2 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55084236; called by muse, mutect2, varscan2
- DLL1 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs769028878, COSV64537474; called by muse, varscan2
- DMD | c.3601A>C p.K1201Q | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1185291494; called by muse, mutect2, varscan2
- DMXL1 | c.7934C>T p.A2645V | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60719530; called by muse, mutect2, varscan2
- DNAH11 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 110/465 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995773912; called by muse, mutect2, varscan2
- DNAH2 | c.6584G>A p.R2195H | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359336800, COSV66721621; called by muse, mutect2, varscan2
- DNAH3 | c.8306C>A p.A2769D | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV99769443; called by muse, mutect2, varscan2
- DNAH8 | c.10495C>T p.R3499C | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758179326, COSV59469603; called by muse, varscan2
- DNAJB14 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1183142425, COSV100508655; called by muse, mutect2, varscan2
- DOC2A | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757458777, COSV100451141, COSV58750916; called by muse, mutect2, varscan2
- DOCK9 | c.5017C>T p.R1673W (on ENST00000376460 / NM_001366676.2; = p.R1674W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as rs556673005; called by muse, mutect2, varscan2
- DOK6 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203760352; called by muse, mutect2, varscan2
- DPEP1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377182881; called by muse, varscan2
- DPEP2 | c.120del p.R41Efs*39 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs547189498; called by mutect2, pindel, varscan2
- DPP3 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs566532784; called by muse, mutect2, varscan2
- DROSHA | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 129/333 reads (39%) | catalogued as rs749032311, COSV60782123; called by muse, mutect2, varscan2
- DSCAM | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 200/544 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV68026184; called by muse, mutect2, varscan2
- DSG2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 173/429 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as rs549421694, COSV55199599; called by muse, mutect2, varscan2
- DTX2 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1424306245; called by muse, varscan2
- DUSP4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as rs1236075524, COSV53546398; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 75/244 reads (31%) | catalogued as rs755197346; called by mutect2, varscan2
- EBF3 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs746403949; called by muse, mutect2, varscan2
- ECD | c.1179A>G p.I393M | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65899787; called by muse, mutect2, varscan2
- ECI1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs773367840, COSV100066508; called by muse, varscan2
- EFCAB2 | c.669A>T p.R223S (on ENST00000366522; = p.R87S on NM_032328.3) | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs1558296590; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as COSV99653876; called by pindel, varscan2*
- EIF2AK2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs747429747, COSV51798081; called by muse, mutect2, varscan2
- EIF2B4 | c.1448G>A p.R483Q (on ENST00000347454 / NM_001034116.2; = p.R482Q on NM_015636.3) | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs776097463; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs759858342; called by mutect2, varscan2
- ENG | c.771del p.Y258Tfs*101 | Frame Shift Del (DEL) | VAF 56/191 reads (29%) | catalogued as CD075380; called by mutect2, pindel, varscan2
- ENO4 | c.848C>T p.S283L (on ENST00000622726; = p.S282L on NM_001242699.2) | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1294513399; called by muse, mutect2, varscan2
- ENPP2 | c.2395C>T p.R799W (on ENST00000075322 / NM_001040092.3; = p.R851W on NM_006209.5) | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370024218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EOMES | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1180443168; called by muse, mutect2, varscan2
- EPHA5 | c.2411G>T p.R804I | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99901584; called by muse, mutect2, varscan2
- EPHA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs369606981, COSV56635227; called by muse, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 72/113 reads (64%) | catalogued as rs756461692; called by mutect2, varscan2
- EQTN | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1264804619; called by muse, mutect2, varscan2
- ESPNL | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs748875074; called by muse, mutect2, varscan2
- EVC | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 161/439 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756208272, COSV53838730, COSV99381347; called by muse, mutect2, varscan2
- EYA4 | c.1688C>T p.A563V (on ENST00000531901 / NM_001301013.1; = p.A557V on NM_004100.5) | Missense Mutation (SNP) | VAF 50/455 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs933456827, COSV62051444; called by muse, mutect2, varscan2
- F12 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1192778187; called by muse, mutect2, varscan2
- FAAP100 | c.2175C>T p.G725= | Splice Region (SNP) | VAF 28/48 reads (58%) | catalogued as rs758795190, COSV59884544; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 49/134 reads (37%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 43/132 reads (33%) | catalogued as rs756478120; called by mutect2, varscan2
- FAM110D | c.484_486del p.K162del | In Frame Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1299602440; called by mutect2, pindel, varscan2
- FAM131A | c.768del p.S257Afs*48 (on ENST00000310585; = p.S288Afs*48 on NM_144635.5) | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV55602091; called by mutect2, pindel, varscan2
- FAM155A | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs752264469; called by muse, mutect2, varscan2
- FAM160A2 | c.1948C>T p.R650C (on ENST00000449352 / NM_001098794.2; = p.R664C on NM_032127.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs749214656, COSV56409753; called by muse, mutect2, varscan2
- FAM187A | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs529160132, COSV53651958; called by muse, mutect2, varscan2
- FAT2 | c.11008A>G p.S3670G | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1348729434; called by muse, mutect2, varscan2
- FAT2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377056065; called by muse, mutect2, varscan2
- FBN2 | c.5311G>T p.A1771S | Missense Mutation (SNP) | VAF 17/484 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52496391; called by muse, mutect2
- FBN3 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs868409562; called by muse, mutect2
- FBRS | c.976G>A p.A326T (on ENST00000287468; = p.A846T on NM_001105079.3) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as rs370683199, COSV99788999; called by muse, mutect2, varscan2
- FBXO40 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573301; called by muse, mutect2, varscan2
- FBXO43 | c.644_646del p.E215del | In Frame Del (DEL) | VAF 50/182 reads (27%) | catalogued as rs768812568; called by pindel, varscan2
- FBXW11 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs1280861852, COSV51615393; called by muse, mutect2, varscan2
- FCRL4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.15); catalogued as rs770243398, COSV99619088; called by muse, mutect2, varscan2
- FGFR3 | c.*894G>A | Splice Region (SNP) | VAF 29/79 reads (37%) | catalogued as rs1293700770; called by muse, mutect2, varscan2
- FJX1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs918783988; called by muse, mutect2
- FLG2 | c.6026A>G p.H2009R | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1366821955; called by muse, mutect2, varscan2
- FLNA | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774810; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 50/164 reads (30%) | catalogued as COSV56098414; called by mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 37/156 reads (24%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXC1 | c.1585T>C p.C529R | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as rs1485476146; called by muse, mutect2
- FOXF2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1243463177; called by muse, varscan2
- FOXL2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57727727; called by muse, mutect2, varscan2
- FOXP4 | c.1235del p.P412Rfs*77 (on ENST00000307972 / NM_001012426.1; = p.P399Rfs*77 on NM_138457.3) | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as COSV57223583; called by mutect2, pindel, varscan2
- FRMD3 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 30/94 reads (32%) | catalogued as COSV100418512; called by muse, varscan2
- FRMD6 | c.1436T>C p.M479T (on ENST00000344768 / NM_001267046.2; = p.M471T on NM_152330.4) | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs752504588; called by muse, mutect2, varscan2
- FRRS1L | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1411339072, COSV73746922; called by muse, mutect2
- FURIN | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176003081, COSV51574849; called by muse, mutect2, varscan2
- FUT1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs541722036, CM1111181, COSV59569245; called by muse, mutect2, varscan2
- FYCO1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138529231; called by muse, mutect2, varscan2
- FZD8 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65968487; called by muse, mutect2, varscan2
- GABBR1 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.499); catalogued as rs1243700899, COSV63542877; called by muse, mutect2, varscan2
- GABRB3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV54683394; called by muse, mutect2, varscan2
- GAL3ST2 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV51951098; called by muse, mutect2, varscan2
- GALNTL5 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 178/666 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101218030, COSV67179543; called by muse, mutect2, varscan2
- GAS6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs747484336; called by muse, varscan2
- GATA2 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV62006102; called by muse, mutect2, varscan2
- GBP5 | c.692del p.K231Rfs*26 | Frame Shift Del (DEL) | VAF 85/351 reads (24%) | catalogued as rs767245260; called by mutect2, pindel, varscan2
- GCN1 | c.6289C>A p.L2097I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56113451; called by muse, mutect2, varscan2
- GDF1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs868299849; called by muse, mutect2, varscan2
- GDF2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1555208722; called by muse, mutect2, varscan2
- GEMIN5 | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768763545, COSV99594234; called by muse, mutect2, varscan2
- GFOD2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs762598999, COSV52060016; called by muse, mutect2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 86/240 reads (36%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA5 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs782580208, COSV54785362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270096533; called by muse, mutect2, varscan2
- GLIS3 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs746828453, COSV60930958; called by muse, mutect2, varscan2
- GOLGA2 | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs1299206643; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 84/224 reads (38%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLPH3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1295953441, COSV54061389; called by muse, mutect2, varscan2
- GPALPP1 | c.969del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 75/707 reads (11%) | catalogued as rs1566086213; called by mutect2, pindel, varscan2
- GPATCH8 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV59192885; called by muse, mutect2, varscan2
- GPBP1 | c.66G>A p.S22= | Splice Region (SNP) | VAF 38/108 reads (35%) | catalogued as rs369233611; called by muse, mutect2, varscan2
- GPR132 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs753534917, COSV61678008; called by muse, mutect2, varscan2
- GPR19 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as rs1475304814; called by muse, mutect2, varscan2
- GPR39 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs750566310, COSV100258105; called by muse, mutect2, varscan2
- GPR6 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV51573229; called by muse, mutect2, varscan2
- GPX5 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 147/387 reads (38%) | catalogued as COSV69079411; called by muse, mutect2, varscan2
- GREB1 | c.5074G>A p.A1692T | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.349); catalogued as rs991868518, COSV52195051; called by muse, mutect2
- GSC | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs772555300; called by muse, mutect2, varscan2
- GSE1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423033999; called by muse, mutect2
- GTF2IRD2B | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554532534; called by mutect2, varscan2
- GTF3C4 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs773416400; called by muse, mutect2, varscan2
- H4C6 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV66685728; called by muse, mutect2
- HAS1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1478264163; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 54/204 reads (26%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HBS1L | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV63200218; called by muse, mutect2
- HCFC1 | c.3518C>T p.A1173V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782596644; called by muse, mutect2, varscan2
- HDAC7 | c.80G>A p.R27H (on ENST00000427332; = p.R66H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs866092952, COSV99315591; called by muse, mutect2, varscan2
- HEMGN | c.1193T>C p.I398T | Missense Mutation (SNP) | VAF 56/864 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as rs772258055; called by muse, mutect2
- HERC2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1465401212, COSV55331317, COSV99876938; called by muse, mutect2
- HHATL | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs746586026, COSV60040810; called by muse, mutect2, varscan2
- HIC1 | c.1165G>A p.A389T (on ENST00000322941 / NM_001098202.1; = p.A370T on NM_006497.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs749428578; called by muse, mutect2, varscan2
- HIRA | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54277132; called by muse, mutect2, varscan2
- HK3 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV52843558; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 59/160 reads (37%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPC | c.467C>T p.S156L (on ENST00000420743; = p.S143L on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/427 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60145066; called by muse, mutect2, varscan2
- HRAS | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV54241530; called by muse, mutect2, varscan2
- HS2ST1 | c.522_524del p.Y175del | In Frame Del (DEL) | VAF 62/259 reads (24%) | catalogued as rs779877914; called by pindel, varscan2
- HS3ST5 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201629220, COSV57139762; called by muse, mutect2
- HSD3B7 | c.543del p.L182Cfs*4 | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | catalogued as COSV52682172; called by mutect2, pindel, varscan2
- HSF1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.932); catalogued as COSV60047501; called by muse, mutect2
- HTR1A | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60501887; called by muse, mutect2, varscan2
- IGFBP3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772535932, COSV51872075; called by muse, mutect2, varscan2
- IGFN1 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV104403032; called by muse, mutect2, varscan2
- IGSF8 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs368177176; called by muse, mutect2, varscan2
- IL16 | c.3143C>T p.S1048L (on ENST00000302987 / NM_172217.5; = p.S347L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57268538; called by muse, mutect2, varscan2
- IL23R | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 19/345 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs758690026, COSV61373282; called by muse, mutect2
- IP6K3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376369600; called by muse, mutect2, varscan2
- IQCH | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 125/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1289802075; called by muse, mutect2, varscan2
- IQGAP1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs773706434; called by muse, mutect2, varscan2
- IQGAP3 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377284542; called by muse, mutect2
- IRS1 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748385460; called by muse, mutect2, varscan2
- IRX3 | c.1113del p.S372Lfs*151 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as rs759120276; called by pindel, varscan2
- ISYNA1 | c.416-3del | Splice Region (DEL) | VAF 8/20 reads (40%) | catalogued as rs764100802; called by mutect2, pindel, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel
- ITGA7 | c.803-5del | Splice Region (DEL) | VAF 58/186 reads (31%) | catalogued as rs1346460062; called by mutect2, pindel, varscan2
- ITGAE | c.1801del p.L601Wfs*82 | Frame Shift Del (DEL) | VAF 79/224 reads (35%) | catalogued as rs867709180; called by mutect2, pindel, varscan2
- ITGAE | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1040691175, COSV99560766; called by muse, mutect2, varscan2
- ITGB2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs764716256; called by muse, mutect2
- ITGB4 | c.3368del p.P1123Lfs*37 | Frame Shift Del (DEL) | VAF 43/153 reads (28%) | catalogued as rs1441262033; called by mutect2, pindel, varscan2
- ITPR2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1473494292, COSV67273903; called by muse, mutect2, varscan2
- JMJD4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 163/368 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs549100036, COSV59919251; called by muse, mutect2, varscan2
- KANK3 | c.1177dup p.A393Gfs*110 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs752726345; called by mutect2, pindel, varscan2
- KAT6A | c.4417G>C p.D1473H | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750883642, COSV99704310; called by muse, mutect2, varscan2
- KAT7 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1475495401; called by muse, mutect2, varscan2
- KAT8 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs759640339; called by muse, mutect2, varscan2
- KBTBD11 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs541540802, COSV57223969; called by muse, mutect2, varscan2
- KCNA5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs763338488; called by muse, mutect2, varscan2
- KCNH2 | c.1946-8G>A | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as rs1384850938; called by muse, mutect2, varscan2
- KCNH3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs141408790, COSV57790082; called by muse, mutect2, varscan2
- KCNJ13 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 154/477 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs17857137; called by muse, mutect2, varscan2
- KCNQ2 | c.1955del p.P652Rfs*278 (on ENST00000359125 / NM_172107.4; = p.P624Rfs*278 on NM_004518.6) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV60550914; called by mutect2, pindel, varscan2
- KCNS1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747780284; called by muse, mutect2, varscan2
- KCNS3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1373662542, COSV58406105; called by muse, mutect2, varscan2
- KCNT1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs751166469; called by muse, mutect2, varscan2
- KDM4A | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs190275733, COSV64959293; called by muse, mutect2, varscan2
- KDM4B | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs369063729; called by muse, mutect2
- KDM5B | c.4600C>T p.R1534C | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs377525543; called by muse, varscan2
- KDM5C | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64763107; called by muse, mutect2, varscan2
- KDM5D | c.4330C>T p.R1444W | Missense Mutation (SNP) | VAF 125/165 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs776718151; called by muse, mutect2, varscan2
- KEAP1 | c.1692dup p.R565Efs*9 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as COSV50660678; called by mutect2, pindel, varscan2
- KEL | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 159/313 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs758195269; called by muse, mutect2, varscan2
- KIAA1586 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as rs1461848373; called by muse, mutect2, varscan2
- KIDINS220 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 105/280 reads (38%) | catalogued as rs763970461, COSV56750845; called by muse, mutect2, varscan2
- KIF19 | c.2104A>G p.S702G | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs939466345; called by muse, mutect2, varscan2
- KIF26A | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59464613; called by muse, mutect2, varscan2
- KIF5A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs780433858; called by muse, mutect2, varscan2
- KIR2DL1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs866902036, COSV99383502; called by muse, mutect2, varscan2
- KIRREL3 | c.464del p.G155Afs*3 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs1565483272; called by mutect2, pindel
- KL | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.806); catalogued as COSV101198998; called by muse, mutect2, varscan2
- KLF10 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 170/556 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1345161159; called by muse, mutect2, varscan2
- KLHL14 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs773956260, COSV63830709; called by muse, mutect2, varscan2
- KLHL25 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs373348206; called by muse, mutect2, varscan2
- KLK15 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs753651539; called by muse, mutect2, varscan2
- KRT40 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 231/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371375504; called by muse, mutect2, varscan2
- KRTDAP | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs746077298, COSV58865245; called by muse, mutect2, varscan2
- LAMB2 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs959473971; called by muse, mutect2, varscan2
- LBHD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs1206660934; called by muse, mutect2, varscan2
- LCA5 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 222/668 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs757969727; called by muse, mutect2, varscan2
- LCE1F | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs766315066; called by muse, mutect2, varscan2
- LCK | c.378-1G>A p.X126_splice | Splice Site (SNP) | VAF 22/57 reads (39%) | catalogued as rs1431441881; called by muse, mutect2, varscan2
- LCP2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as rs747523987, COSV50447368; called by muse, mutect2, varscan2
- LCTL | c.796del p.E266Nfs*11 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs1409433509, COSV100427282; called by mutect2, pindel, varscan2
- LDHA | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 153/755 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV57039493; called by muse, mutect2, varscan2
- LEFTY2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375598455; called by muse, mutect2, varscan2
- LHCGR | c.1764dup p.A589Cfs*17 | Frame Shift Ins (INS) | VAF 233/702 reads (33%) | catalogued as rs1293879367; called by mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 78/194 reads (40%) | catalogued as rs748571616; called by mutect2, varscan2
- LINGO1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs746499302, COSV62437503; called by muse, mutect2, varscan2
- LITAF | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 128/345 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs753060675; called by muse, mutect2, varscan2
- LMF2 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as rs760890488; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 143/443 reads (32%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRIG3 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs1446034098; called by muse, mutect2, varscan2
- LRP2BP | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs111547365; called by muse, mutect2, varscan2
- LRPPRC | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs182612310, COSV99580613; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 48/157 reads (31%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC66 | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 153/501 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs1164814700; called by muse, mutect2, varscan2
- LRRC9 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1175476030, COSV99580562; called by muse, mutect2, varscan2
- LRRC9 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758764289; called by muse, mutect2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 130/526 reads (25%) | catalogued as rs747411092; called by mutect2, varscan2
- LRRN4CL | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294784510; called by muse, mutect2, varscan2
- LSAMP | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 216/659 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as rs1329182222, COSV100372744, COSV61300700; called by muse, mutect2, varscan2
- LSM4 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs764476513, COSV99416841; called by muse, mutect2, varscan2
- LSMEM2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782440636, COSV100269350; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs936902223; called by muse, mutect2, varscan2
- LY9 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139498658; called by muse, mutect2, varscan2
- MAD1L1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs371823704; called by muse, mutect2, varscan2
- MALRD1 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs773226032; called by muse, mutect2
- MAP3K10 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs757704923; called by muse, mutect2, varscan2
- MAP3K3 | c.1094del p.G365Efs*42 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | catalogued as COSV62280848; called by mutect2, pindel, varscan2
- MAP4K5 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368497445, COSV50152507; called by muse, mutect2, varscan2
- MAP7D1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426629110, COSV60219033; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 35/186 reads (19%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MAST2 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.045); catalogued as rs368622066; called by muse, mutect2, varscan2
- MASTL | c.1372dup p.I458Nfs*5 | Frame Shift Ins (INS) | VAF 152/472 reads (32%) | catalogued as rs780698479; called by mutect2, varscan2
- MATN1 | c.85dup p.Q29Pfs*28 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs1419789464; called by mutect2, pindel, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs767720617; called by mutect2, varscan2
- MBTPS1 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs756001167, COSV100597523; called by muse, mutect2, varscan2
- MCF2L | c.409C>T p.R137W (on ENST00000375608; = p.R105W on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368238188, COSV65051233; called by muse, mutect2, varscan2
- MCM9 | c.2464del p.R822Gfs*2 | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | catalogued as rs1298669721; called by mutect2, varscan2
- MECP2 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs1557134990; called by muse, mutect2, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 13/87 reads (15%) | catalogued as rs772983071; called by mutect2, varscan2
- MEGF11 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178836321; called by muse, varscan2
- MEIOC | c.2361del p.V788Yfs*12 | Frame Shift Del (DEL) | VAF 97/260 reads (37%) | catalogued as rs746201258; called by mutect2, varscan2
- MEMO1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs143148468; called by muse, mutect2, varscan2
- MESP2 | c.718del p.V240Sfs*241 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | catalogued as rs756232049; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MGA | c.7469G>A p.R2490Q (on ENST00000219905 / NM_001164273.1; = p.R2281Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs774387775, COSV104376779; called by muse, mutect2, varscan2
- MIA2 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.168); catalogued as rs778696382; called by muse, mutect2
- MICALL1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1190990003, COSV99317023; called by muse, mutect2, varscan2
- MIER2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); catalogued as rs762103363, COSV53397057; called by muse, mutect2, varscan2
- MINAR1 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | catalogued as COSV100548719; called by muse, mutect2, varscan2
- MMP15 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs765310950, COSV54681293; called by muse, mutect2, varscan2
- MMP2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs375159741; called by muse, mutect2, varscan2
- MOGS | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431008691; called by muse, mutect2, varscan2
- MOV10 | c.2009A>G p.D670G | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV53518801; called by muse, mutect2
- MPDZ | c.3106A>G p.I1036V | Missense Mutation (SNP) | VAF 166/428 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as rs1435912430; called by muse, mutect2, varscan2
- MPO | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as COSV56562649, COSV99034589; called by muse, mutect2, varscan2
- MPO | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs763622732; called by muse, mutect2, varscan2
- MRM1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756123716; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | catalogued as rs1558718327, COSV62567684; called by mutect2, pindel, varscan2
- MRPL2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759643666; called by muse, mutect2
- MRPL32 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as rs139835970; called by muse, mutect2, varscan2
- MRPS5 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 150/399 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1269130784; called by muse, mutect2, varscan2
- MTCL1 | c.5579A>G p.H1860R (on ENST00000306329 / NM_001378206.1; = p.H1541R on NM_015210.4) | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs923718876; called by muse, mutect2, varscan2
- MTRF1L | c.753del p.Q252Sfs*3 | Frame Shift Del (DEL) | VAF 114/397 reads (29%) | catalogued as rs762360173; called by mutect2, pindel, varscan2
- MUC16 | c.37855C>T p.R12619C | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs765697877, COSV67444013; called by muse, mutect2, varscan2
- MUC16 | c.10117G>A p.V3373I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.096); catalogued as rs769634596; called by muse, mutect2, varscan2
- MUC3A | c.8594G>A p.R2865Q | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768338645, COSV60221474; called by muse, mutect2
- MXRA5 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759774377; called by muse, mutect2, varscan2
- MYBPC2 | c.2926del p.T976Pfs*76 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs757263482; called by mutect2, pindel, varscan2
- MYH10 | c.5584C>T p.R1862C | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780650576, COSV52610206; called by muse, mutect2, varscan2
- MYH10 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs552031621, COSV52596701; called by muse, mutect2, varscan2
- MYLK | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 128/320 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs34542174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1C | c.2828C>T p.T943M (on ENST00000648651 / NM_001080779.2; = p.T908M on NM_033375.5) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs367849804; called by muse, mutect2, varscan2
- MYO1C | c.1123G>A p.A375T (on ENST00000648651 / NM_001080779.2; = p.A340T on NM_033375.5) | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs780926824; called by muse, mutect2, varscan2
- MYO1C | c.740G>A p.G247D (on ENST00000648651 / NM_001080779.2; = p.G212D on NM_033375.5) | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759969887, COSV100704262, COSV62998764; called by muse, mutect2, varscan2
- NAT16 | c.209_210insA p.I73Hfs*10 | Frame Shift Ins (INS) | VAF 62/283 reads (22%) | catalogued as COSV55865184; called by mutect2, pindel, varscan2
- NAV2 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1377815291; called by muse, mutect2, varscan2
- NCAPD3 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1213876164; called by muse, varscan2
- NCKAP1 | c.2551C>A p.L851I | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV62941633; called by muse, mutect2, varscan2
- NCKAP5 | c.5342G>A p.R1781H | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755560675; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel, varscan2
- NCOR2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs370196674; called by muse, mutect2
- NDUFV1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs773211506; called by muse, mutect2, varscan2
- NELFE | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs772078692, COSV99064754; called by muse, mutect2, varscan2
- NES | c.2060A>C p.E687A | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100957788; called by muse, mutect2, varscan2
- NEUROD1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.104); catalogued as rs1390171738; called by muse, mutect2, varscan2
- NF1 | c.2903T>C p.M968T | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as CM030257; called by muse, mutect2
- NF1 | c.4958G>A p.R1653H (on ENST00000358273 / NM_001042492.3; = p.R1632H on NM_000267.3) | Missense Mutation (SNP) | VAF 112/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs763413441, COSV55985392, COSV55985631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.2053G>A p.V685I (on ENST00000339876 / NM_001378329.1; = p.V681I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs771862901, COSV58357612; called by muse, mutect2, varscan2
- NFIX | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62175972; called by muse, mutect2, varscan2
- NFXL1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748118226; called by muse, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 112/298 reads (38%) | catalogued as rs1171412241, CD054388; called by mutect2, varscan2
- NHLRC2 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65175797; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 78/274 reads (28%) | catalogued as rs111948120; called by pindel, varscan2
- NKAPL | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1228592352; called by muse, mutect2, varscan2
- NKX2-4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs924791828, COSV100698580; called by muse, varscan2
- NLRP1 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs193920788, COSV52557794, COSV52567498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL4 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs746220512, COSV52341252; called by muse, mutect2, varscan2
- NOS1 | c.3536A>G p.Y1179C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57619510; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 71/254 reads (28%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH3 | c.6102dup p.G2035Rfs*60 | Frame Shift Ins (INS) | VAF 40/52 reads (77%) | catalogued as rs771517374; called by mutect2, varscan2
- NPAS3 | c.1000G>A p.V334I (on ENST00000356141 / NM_001164749.2; = p.V302I on NM_022123.3) | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs777057923, COSV60824621; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 82/219 reads (37%) | catalogued as rs776154715; called by mutect2, varscan2
- NSG2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766024271, COSV57456632; called by muse, mutect2, varscan2
- NTSR2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs767804665; called by muse, mutect2, varscan2
- NWD1 | c.4177T>G p.C1393G | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763989600; called by muse, mutect2, varscan2
- OBSCN | c.1604del p.P535Hfs*16 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as COSV52744319; called by mutect2, pindel, varscan2
- OBSCN | c.3869C>T p.T1290M | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs373940171; called by muse, mutect2, varscan2
- OBSL1 | c.458del p.G153Afs*105 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as CX132462; called by mutect2, pindel, varscan2
- OCSTAMP | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as rs1262783199; called by muse, mutect2, varscan2
- OPN5 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373745956, COSV55246635; called by muse, mutect2, varscan2
- OR1C1 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as COSV68715537, COSV68716159; called by muse, mutect2, varscan2
- OR1M1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1177569351, COSV70036422; called by muse, mutect2, varscan2
- OR51T1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs768466143, COSV59023680; called by muse, mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 42/156 reads (27%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- OR6C1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs979947032, COSV65573912; called by muse, mutect2, varscan2
- OR8B3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs755136502; called by mutect2, pindel, varscan2
- OR8S1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59599649; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as rs750679212; called by mutect2, varscan2
- OTOP3 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV60914507; called by muse, varscan2
- OTX1 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774184032; called by muse, mutect2, varscan2
- OXCT1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV52178940; called by muse, mutect2, varscan2
- PALM | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs1306293189; called by muse, mutect2, varscan2
- PAOX | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768196529, COSV53371654; called by muse, mutect2, varscan2
- PBRM1 | c.3427C>A p.P1143T (on ENST00000296302 / NM_001366071.2; = p.P1118T on NM_018313.5) | Missense Mutation (SNP) | VAF 147/378 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV56264350, COSV56280719; called by muse, mutect2, varscan2
- PCDH15 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 195/599 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57352641; called by muse, mutect2, varscan2
- PCDHA1 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as rs1554118218, COSV65373104; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56553142; called by muse, mutect2, varscan2
- PCDHA6 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV65350846, COSV65355737; called by muse, mutect2, varscan2
- PCDHB1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554267179, COSV60631745, COSV60633356; called by muse, mutect2, varscan2
- PCDHB4 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99078126; called by muse, mutect2, varscan2
- PCDHGA1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs781601310; called by muse, mutect2, varscan2
- PCDHGA6 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 87/265 reads (33%) | catalogued as rs1366674805, COSV53931781; called by muse, mutect2, varscan2
- PCDHGA6 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as rs181747779, COSV53986672; called by muse, mutect2, varscan2
- PCDHGB2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs575415323, COSV54013995; called by muse, mutect2, varscan2
- PCDHGB3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV53904567; called by muse, mutect2, varscan2
- PCDHGB4 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs771332132; called by muse, mutect2, varscan2
- PCDHGB6 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.473); catalogued as COSV53901987; called by muse, varscan2
- PCM1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758246567, COSV100279438; called by muse, mutect2, varscan2
- PCNT | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 123/337 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1440769686; called by muse, mutect2, varscan2
- PDILT | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100199885; called by muse, mutect2, varscan2
- PDZD2 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 120/311 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs577368144; called by muse, mutect2, varscan2
- PGR | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV54798727; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs749326031; called by pindel, varscan2
- PHKG2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779515173, COSV60313653; called by muse, mutect2, varscan2
- PHLDA3 | c.265dup p.L89Pfs*? (on ENST00000367309; = p.L89Pfs*138 on NM_012396.5) | Frame Shift Ins (INS) | VAF 30/112 reads (27%) | catalogued as rs1245629568; called by mutect2, pindel, varscan2
- PHLDB1 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782328887; called by muse, mutect2, varscan2
- PIEZO2 | c.5395G>A p.V1799M | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1404474119; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 38/153 reads (25%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PKD1 | c.6526C>T p.R2176C | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746489969; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel, varscan2
- PLAAT5 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV100080482; called by muse, mutect2
- PLAGL1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1187230713; called by muse, mutect2, varscan2
- PLB1 | c.4081G>A p.A1361T | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749695328, COSV59832429; called by muse, mutect2, varscan2
- PLEC | c.5930C>T p.A1977V (on ENST00000322810 / NM_201380.4; = p.A1867V on NM_000445.5) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100518140; called by muse, mutect2, varscan2
- PLEKHA6 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs529169780; called by muse, mutect2, varscan2
- PLEKHN1 | c.1901A>G p.H634R (on ENST00000379409; = p.H582R on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.106); catalogued as COSV58021280; called by muse, mutect2, varscan2
- PLK1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1379177197, COSV55622956; called by muse, mutect2, varscan2
- PLXNA2 | c.1393dup p.H465Pfs*27 | Frame Shift Ins (INS) | VAF 13/61 reads (21%) | catalogued as rs752105673; called by mutect2, varscan2
- PLXNB3 | c.4963dup p.V1655Gfs*76 | Frame Shift Ins (INS) | VAF 12/16 reads (75%) | catalogued as rs782076287; called by mutect2, varscan2
- PNPLA6 | c.1985G>A p.R662H (on ENST00000414982 / NM_001166111.2; = p.R614H on NM_006702.5) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1489744966, COSV55375843; called by muse, mutect2, varscan2
- PNPLA6 | c.2416G>A p.A806T (on ENST00000414982 / NM_001166111.2; = p.A758T on NM_006702.5) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs144206674; called by muse, mutect2, varscan2
- PNPLA6 | c.2470C>T p.R824C (on ENST00000414982 / NM_001166111.2; = p.R776C on NM_006702.5) | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs531445564, COSV55375072; called by muse, mutect2, varscan2
- POLK | c.507del p.N170Tfs*8 | Frame Shift Del (DEL) | VAF 152/487 reads (31%) | catalogued as rs758745741; called by mutect2, pindel, varscan2
- POLR1A | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777068250; called by muse, mutect2, varscan2
- POTEA | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.148); catalogued as rs1231215026; called by muse, mutect2, varscan2
- POTEE | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 193/1212 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs747324485, COSV58238683; called by muse, mutect2, varscan2
- POTEG | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 139/1464 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.975); catalogued as rs376547042, COSV73631102; called by muse, varscan2
- POU4F2 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV55582926; called by muse, varscan2
- PPARGC1B | c.2199G>T p.Q733H | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58528498; called by muse, mutect2, varscan2
- PPIL2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs561147309, COSV58605424; called by muse, mutect2, varscan2
- PPL | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560350086, COSV52167771; called by muse, mutect2, varscan2
- PPL | c.1362dup p.T455Hfs*4 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | catalogued as rs753902804; called by mutect2, varscan2
- PPP2R5D | c.36del p.K13Rfs*94 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as COSV57840074; called by mutect2, pindel, varscan2
- PRAMEF10 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1356419826; called by muse, mutect2, varscan2
- PRAMEF17 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs1173726239; called by muse, varscan2
- PRDM16 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772868294, COSV54611602; called by muse, mutect2, varscan2
- PRDM16 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs753949982; called by muse, mutect2, varscan2
- PRDM7 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV57987772; called by muse, mutect2, varscan2
- PREX1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs1381418200, COSV64254516; called by muse, mutect2, varscan2
- PRG4 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100798145; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 78/231 reads (34%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 54/106 reads (51%) | catalogued as rs764069617; called by mutect2, varscan2
- PRKCQ | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370703516, COSV54105311; called by muse, mutect2, varscan2
- PRKRIP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 30/199 reads (15%) | catalogued as rs782018191; called by muse, mutect2, varscan2
- PRR14 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54912027; called by muse, mutect2, varscan2
- PRR16 | c.320del p.P107Qfs*11 (on ENST00000407149 / NM_001300783.2; = p.P84Qfs*11 on NM_016644.2) | Frame Shift Del (DEL) | VAF 80/263 reads (30%) | catalogued as rs1371403180; called by mutect2, pindel, varscan2
- PRR23A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs765076882, COSV67214626, COSV67214848; called by muse, mutect2
- PRR32 | c.675G>A p.W225* | Nonsense Mutation (SNP) | VAF 85/114 reads (75%) | catalogued as COSV64420464; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSD | c.676del p.R226Gfs*68 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs772089836; called by mutect2, pindel, varscan2
- PSG8 | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764813765, COSV60610556; called by muse, mutect2
- PTCD3 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 98/263 reads (37%) | catalogued as rs1468225992; called by muse, mutect2, varscan2
- PTPN12 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.1); catalogued as rs977073067; called by muse, mutect2, varscan2
- PTPRCAP | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV57055486; called by muse, mutect2, varscan2
- PUM1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.267); catalogued as rs752999527; called by muse, mutect2, varscan2
- PWWP3B | c.916del p.A306Lfs*29 | Frame Shift Del (DEL) | VAF 15/23 reads (65%) | catalogued as COSV100531264; called by mutect2, pindel, varscan2
- PXMP4 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 116/322 reads (36%) | catalogued as rs201904586, COSV54133033; called by muse, mutect2, varscan2
- R3HDM1 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 157/432 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51526518; called by muse, mutect2, varscan2
- RABGAP1L | c.1942T>C p.Y648H | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1185950720; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | catalogued as rs745353960; called by mutect2, varscan2
- RAD51B | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 177/453 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1171289062; called by muse, mutect2, varscan2
- RANBP17 | c.1884del p.K628Nfs*3 | Frame Shift Del (DEL) | VAF 57/202 reads (28%) | catalogued as COSV101206115; called by mutect2, pindel, varscan2
- RASGEF1A | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs776561636, COSV65666808; called by muse, mutect2, varscan2
- RASIP1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1314307287, COSV55802765; called by muse, mutect2, varscan2
- RASL10A | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs912333096; called by muse, mutect2, varscan2
- RB1CC1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 123/353 reads (35%) | catalogued as rs1563437586, COSV50258374; called by muse, mutect2, varscan2
- RBM14 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs930621157; called by muse, mutect2, varscan2
- RCC1L | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 157/317 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781822837; called by muse, mutect2, varscan2
- REG3A | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 92/207 reads (44%) | catalogued as COSV59409239; called by muse, mutect2, varscan2
- REV3L | c.4211G>A p.R1404H | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs985550312, COSV100725342; called by muse, mutect2, varscan2
- REXO1 | c.2959C>A p.R987S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV50079710; called by muse, mutect2, varscan2
- RFPL1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585862; called by muse, mutect2, varscan2
- RFX6 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 220/557 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60584144; called by muse, mutect2, varscan2
- RGL4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1467976178; called by muse, mutect2, varscan2
- RHBDF1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 61/136 reads (45%) | catalogued as rs761693781, COSV51953896; called by muse, mutect2, varscan2
- RIC8A | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs772146366; called by muse, mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 109/374 reads (29%) | catalogued as COSV54616696; called by mutect2, pindel, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs761874510; called by mutect2, pindel
- RNF167 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs760638375, COSV99337215; called by muse, mutect2, varscan2
- RNF208 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1170699516; called by muse, mutect2
- RNF217 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs777176681; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 39/133 reads (29%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO4 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100127172; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 93/297 reads (31%) | catalogued as rs1392239785; called by mutect2, pindel, varscan2
- RPRD1B | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs200179296, COSV65033071, COSV65033831; called by muse, mutect2, varscan2
- RPTOR | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60816058; called by muse, mutect2, varscan2
- RRAGC | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1327011466; called by muse, mutect2, varscan2
- RUFY1 | c.1957_1959del p.K653del | In Frame Del (DEL) | VAF 50/192 reads (26%) | catalogued as rs777382030; called by mutect2, pindel, varscan2
- RUFY2 | c.1543A>C p.I515L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56258621; called by muse, mutect2, varscan2
- RUSC2 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs188737758; called by muse, mutect2, varscan2
- RYR2 | c.1614G>A p.A538= | Splice Region (SNP) | VAF 71/250 reads (28%) | catalogued as rs566885717, COSV63688605; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- SAFB2 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs755798347, COSV53040566; called by muse, mutect2
- SAFB2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766256654; called by muse, mutect2, varscan2
- SBF1 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs767810845; called by muse, mutect2, varscan2
- SBNO1 | c.3905G>A p.R1302H (on ENST00000420886; = p.R1301H on NM_018183.5) | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV57347449; called by muse, mutect2, varscan2
- SCAPER | c.2613dup p.A872Sfs*13 | Frame Shift Ins (INS) | VAF 116/350 reads (33%) | catalogued as rs757259031; called by mutect2, varscan2
- SCART1 | c.2276-5C>T | Splice Region (SNP) | VAF 37/139 reads (27%) | catalogued as rs770031852; called by muse, varscan2
- SCML4 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs769590136, COSV64636916; called by muse, mutect2, varscan2
- SCN10A | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778131235, COSV71861217, COSV71862603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.5689C>T p.R1897W (on ENST00000333535 / NM_198056.3; = p.R1896W on NM_000335.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs45465995, CM097690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs573462705; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEMA5A | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1436765433, COSV66793308; called by muse, mutect2, varscan2
- SEMA6B | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1279041694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs1184198853; called by muse, varscan2
- SEPTIN2 | c.129C>T p.V43= | Splice Region (SNP) | VAF 56/156 reads (36%) | catalogued as rs779757638, COSV63471991; called by muse, mutect2, varscan2
- SERPINA4 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs770272743; called by muse, mutect2, varscan2
- SETD1B | c.5569G>A p.V1857M | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99930948; called by muse, mutect2
- SETDB1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs144623268; called by muse, mutect2, varscan2
- SETX | c.7330C>T p.R2444C | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372535542, CM087874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D3C | c.826G>A p.E276K (on ENST00000314830 / NM_170600.3; = p.E119K on NM_005489.4) | Missense Mutation (SNP) | VAF 131/351 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs570813230, COSV100136432; called by muse, mutect2, varscan2
- SH3PXD2A | c.2587G>A p.A863T (on ENST00000369774 / NM_001365079.1; = p.A835T on NM_014631.2) | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs766798828, COSV60116246; called by muse, mutect2, varscan2
- SHANK1 | c.5435C>T p.A1812V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.151); catalogued as rs749037124, COSV53255448; called by muse, mutect2, varscan2
- SHARPIN | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs539568406; called by muse, mutect2, varscan2
- SHC4 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1439232930; called by muse, mutect2, varscan2
- SI | c.3593dup p.L1198Ffs*14 | Frame Shift Ins (INS) | VAF 167/586 reads (28%) | catalogued as rs1222601003; called by mutect2, pindel, varscan2
- SIPA1L3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs754702591, COSV99730199; called by muse, mutect2, varscan2
- SLC13A5 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 74/195 reads (38%) | catalogued as COSV99545937; called by muse, mutect2, varscan2
- SLC15A1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 188/334 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs771067175, COSV64731790; called by muse, mutect2, varscan2
- SLC16A14 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1205196087, COSV54617922; called by muse, mutect2, varscan2
- SLC22A6 | c.777dup p.A260Cfs*11 | Frame Shift Ins (INS) | VAF 23/84 reads (27%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC23A1 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs756842191; called by muse, mutect2, varscan2
- SLC25A47 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1248512079; called by muse, mutect2, varscan2
- SLC26A5 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 204/711 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV59706746; called by muse, mutect2, varscan2
- SLC35A5 | c.898del p.Y300Mfs*8 | Frame Shift Del (DEL) | VAF 59/330 reads (18%) | catalogued as rs1363537717; called by mutect2, pindel, varscan2
- SLC40A1 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 96/394 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs564905172, COSV53724741; called by muse, mutect2, varscan2
- SLC47A2 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs751597777, COSV100328164; called by muse, mutect2, varscan2
- SLC4A5 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1553452434, COSV61030120; called by muse, mutect2, varscan2
- SLC5A11 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs552396984; called by muse, mutect2, varscan2
- SLC9A7 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 149/214 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs375953952, COSV60378801; called by muse, mutect2, varscan2
- SLIT2 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.445); catalogued as COSV56561123, COSV99888209; called by muse, mutect2, varscan2
- SLITRK5 | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs756482226; called by muse, mutect2, varscan2
- SLX4 | c.5080G>A p.A1694T | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs1218491919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 82/207 reads (40%) | catalogued as rs1461272768, COSV57645914; called by muse, mutect2, varscan2
- SNED1 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs779036938, COSV60026747; called by muse, mutect2, varscan2
- SNIP1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1478911110; called by muse, mutect2, varscan2
- SNRNP70 | c.46del p.R16Vfs*95 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | catalogued as rs1183371144; called by mutect2, pindel, varscan2
- SNTB2 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs375616677; called by muse, mutect2, varscan2
- SNX13 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV101285051; called by muse, mutect2
- SNX20 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100319294; called by muse, mutect2, varscan2
- SOCS6 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 49/505 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV67547192; called by muse, mutect2
- SORCS2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs779383513, COSV100214076; called by muse, mutect2, varscan2
- SOX13 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs762506053, COSV65826750; called by muse, mutect2, varscan2
- SP3 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100022144; called by muse, mutect2
- SPAG6 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 150/412 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs749967665, COSV57624170; called by muse, mutect2, varscan2
- SPATA20 | c.1195G>A p.A399T (on ENST00000356488 / NM_001258372.1; = p.A415T on NM_022827.4) | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs374270120; called by muse, mutect2, varscan2
- SPATA20 | c.1683del p.T562Lfs*73 (on ENST00000356488 / NM_001258372.1; = p.T578Lfs*73 on NM_022827.4) | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs748942419; called by mutect2, pindel
- SPATA31D1 | c.2417A>G p.E806G | Missense Mutation (SNP) | VAF 180/461 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as rs992271271, COSV61192820; called by muse, mutect2, varscan2
- SPATA7 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs775594191; called by muse, mutect2, varscan2
- SPEF2 | c.700del p.M234* | Frame Shift Del (DEL) | VAF 97/333 reads (29%) | catalogued as rs528892977; called by mutect2, pindel, varscan2
- SPEG | c.9742C>T p.R3248C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs1357626784; called by muse, mutect2, varscan2
- SPEN | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); catalogued as rs745325343; called by muse, mutect2, varscan2
- SPEN | c.8668G>A p.A2890T | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs768779200; called by muse, mutect2, varscan2
- SPOUT1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1340581066; called by muse, mutect2, varscan2
- SPP2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs201489523; called by muse, mutect2, varscan2
- SPRR2E | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV64203994, COSV64204055; called by muse, mutect2, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 34/124 reads (27%) | catalogued as rs567805129; called by mutect2, varscan2
- SPRY4 | c.761C>T p.A254V (on ENST00000434127 / NM_001127496.3; = p.A277V on NM_030964.4) | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59986255; called by muse, mutect2, varscan2
- SPTA1 | c.1584G>T p.Q528H | Missense Mutation (SNP) | VAF 191/528 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV63750507; called by muse, mutect2, varscan2
- SRCAP | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760183638, COSV99349532; called by muse, mutect2, varscan2
- SRD5A1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs545726471, COSV57014616; called by muse, mutect2, varscan2
- SREBF1 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs761664089; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs750306056; called by mutect2, varscan2
- STIMATE | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1276988897; called by muse, mutect2, varscan2
- STX1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs782606855; called by muse, mutect2
- STX1A | c.466+2T>C p.X156_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as rs782612195; called by muse, mutect2
- SUCLG2 | c.1316del p.L439Yfs*8 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs757697438; called by mutect2, pindel
- SUGP1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1486997637; called by muse, mutect2, varscan2
- SULT1A1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs752498609; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT5H | c.2506T>C p.Y836H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.815); catalogued as rs1318889234; called by muse, mutect2, varscan2
- SUSD5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768816890; called by muse, mutect2, varscan2
- SYNM | c.4447G>A p.G1483S (on ENST00000336292 / NM_145728.3; = p.G1171S on NM_015286.6) | Missense Mutation (SNP) | VAF 158/366 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as rs781980857; called by muse, mutect2, varscan2
- SYT5 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1238619033; called by muse, mutect2
- SZT2 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1486824755; called by muse, mutect2, varscan2
- TAF6 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs762614153, COSV59840907; called by muse, varscan2
- TAMALIN | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1200133966; called by muse, mutect2, varscan2
- TBC1D30 | c.2152G>A p.E718K (on ENST00000542120; = p.E555K on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.241); catalogued as rs772258001; called by muse, mutect2, varscan2
- TBL1XR1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as rs1278353453, COSV70502086; called by muse, varscan2
- TBL2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs1554588344, COSV59786272; called by muse, mutect2, varscan2
- TBX18 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1177233282; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 46/161 reads (29%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF12 | c.546del p.V183Sfs*62 | Frame Shift Del (DEL) | VAF 132/456 reads (29%) | catalogued as rs1352708150; called by mutect2, pindel, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as rs745872748; called by mutect2, varscan2
- TCP1 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs747455768; called by muse, mutect2, varscan2
- TEPSIN | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs147617220; called by muse, mutect2, varscan2
- TFPT | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs1360427920, COSV99063773; called by muse, mutect2, varscan2
- THSD4 | c.2443C>T p.R815W | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367982245, COSV55970013; called by muse, mutect2, varscan2
- TM2D2 | c.322G>A p.G108S (on ENST00000456397 / NM_078473.3; = p.G65S on NM_031940.4) | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765267190, COSV56761487; called by muse, mutect2, varscan2
- TMCC1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs764293379; called by muse, mutect2, varscan2
- TMEM109 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs765962512; called by muse, mutect2, varscan2
- TMEM119 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748217651, COSV101219581; called by muse, mutect2, varscan2
- TMEM132A | c.1507G>A p.D503N (on ENST00000453848 / NM_178031.3; = p.D504N on NM_017870.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767309456; called by muse, mutect2, varscan2
- TMEM225 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100902837; called by muse, mutect2, varscan2
- TMEM229B | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs761111879; called by muse, mutect2, varscan2
1,820 further variants in this file (1,007 protein-altering or splice-affecting, 486 silent, 327 other) are not listed here.
